Somatic mutation profile of tumor specimen 0DHHJS from CCDI case PBBUNA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebrum; Age at diagnosis: 7.0 years (2,563 days).
Specimen 0DHHJS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86cd9e8b-d84f-4fda-91ad-773e9ea26a0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHHIY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a60dcb0-02fe-4a2e-afd4-be9691e963d7

The open-access MAF lists 46 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 8, Intron 6, Silent 6, Nonsense Mutation 2, Splice Site 2, 5'UTR 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 138/567 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>G p.Y163D | Missense Mutation (SNP) | VAF 68/118 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCOR | c.1527G>A p.W509* | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | catalogued as COSV60700663; called by muse, mutect2, varscan2
- DZIP3 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 273/1064 reads (26%) | catalogued as rs1188729389, COSV64313452; called by muse, mutect2, varscan2
- FRY | c.4592G>A p.G1531E | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100969314; called by muse, mutect2, varscan2
- SMC3 | c.273del p.I91Mfs*21 | Frame Shift Del (DEL) | VAF 44/394 reads (11%) | catalogued as COSV62419389, COSV62422052; called by mutect2, varscan2
- TEX13D | c.1086G>C p.M362I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs1364180197, COSV69794684; called by mutect2, varscan2
- TEX13D | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV69794686; called by muse, mutect2, varscan2
- ZFHX4 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 142/420 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as rs780029176, COSV51491373; called by muse, mutect2, varscan2
- ARHGEF15 | c.1133A>T p.N378I | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); called by muse, varscan2
- ARHGEF6 | c.1704T>G p.S568= | Splice Region (SNP) | VAF 158/645 reads (24%) | called by muse, mutect2, varscan2
- C1QB | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.05); called by muse, varscan2
- CACNA1C | c.5081A>T p.D1694V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, varscan2
- CATSPERG | c.1686A>T p.L562F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- DYNC1H1 | c.4775T>A p.L1592Q | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 38/360 reads (11%) | called by muse, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 36/351 reads (10%) | called by muse, varscan2
- IGF2 | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by mutect2, varscan2
- KCNJ18 | c.541A>T p.M181L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, varscan2
- KDELR1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRAP | c.1843G>C p.V615L (on ENST00000359988 / NM_001322945.2; = p.V580L on NM_006175.4) | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.115); called by muse, varscan2
- NUP93 | c.42A>T p.E14D | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2
- OPRL1 | c.760A>C p.K254Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PSD3 | c.819G>C p.R273S | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); called by muse, varscan2
- ACKR3 | c.127C>T p.L43= | Silent (SNP) | VAF 64/190 reads (34%) | called by muse, mutect2, varscan2
- ACRBP | c.15C>G p.A5= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs143135414; called by muse, varscan2
- GRIP2 | c.219G>A p.L73= | Silent (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- NXPH4 | c.798C>G p.A266= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- PPP1R10 | c.2094A>T p.P698= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs765853010; called by mutect2, varscan2
- RGS12 | c.1803G>A p.E601= | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/109 reads (11%) | called by muse, varscan2
- CSF2RA | c.*106T>A | 3'UTR (SNP) | VAF 39/310 reads (13%) | called by muse, varscan2
- CYB5RL | c.348-87G>T | Intron (SNP) | VAF 3/20 reads (15%) | called by mutect2, varscan2
- CYB5RL | c.348-88T>C | Intron (SNP) | VAF 3/20 reads (15%) | called by mutect2, varscan2
- DHX16 | c.*60C>G | 3'UTR (SNP) | VAF 20/185 reads (11%) | called by muse, varscan2
- DOT1L | c.*314A>T | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, varscan2
- FBXL18 | c.*4323A>G | 3'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99987084; called by muse, varscan2
- LSM14A | c.*123G>T | 3'UTR (SNP) | VAF 37/728 reads (5%) | called by muse, mutect2
- LTBP4 | c.1627+64T>C | Intron (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- MALRD1 | c.6315-99C>A | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 42/326 reads (13%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 32/224 reads (14%) | called by muse, varscan2
- UCN2 | c.*29G>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- UNK | c.*71G>T | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, varscan2
